Gene-level copy-number profile of specimen HCM-CSHL-0768-C56-85O from HCMI case HCM-CSHL-0768-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage II; Tumor grade: High Grade.
Specimen HCM-CSHL-0768-C56-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c790b6eb-eb10-4ed2-a6ec-814e2b90527c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0768-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,271 have no estimate.
https://portal.gdc.cancer.gov/files/9e32d378-3ea0-460d-ac3d-589dce05b628

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 29; copy number 2: 21,914; copy number 3: 27,615; copy number 4: 6,643; copy number 5: 130; copy number 6: 295; copy number 7: 2; copy number 8: 1,386; copy number 9: 222; copy number 10: 29; copy number 12: 27; copy number 14: 1; copy number 21: 9; copy number 28: 1; copy number 29: 4; copy number 30: 7; copy number 33: 8; copy number 36: 2; copy number 37: 5; copy number 42: 3; copy number 54: 2; copy number 55: 6; copy number 57: 8; copy number 58: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,726 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:629,062–686,673, 10 genes, copy number 10: MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16.
- chr8:39,451,045–145,066,685, 1,596 genes, copy number 8–21 (broad region; genes not listed).
- chr12:18,683,169–23,251,499, 69 genes, copy number 8–37 (broad region; genes not listed).
- chr12:24,566,964–26,833,194, 48 genes, copy number 12–58 (within-gene range 3–58): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354.
- chr12:37,575,587–37,576,384, 1 gene, copy number 10: ZNF970P.
- chr14:105,583,731–105,601,728, 2 genes, copy number 7: IGHA2, IGHE.

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
